Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADE-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0 8170/3
pJ 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen: Fresh

Liver: 14.0 x 11.5 x 6.5 cm, 333.5 gm

Gallbladder: 8.5 cm in length, 3.0 cm in diameter, 0.1 cm in wall thickness

Operation: Lobectomy

Lesion: A well-defined mass

Size: 9.0 x 9.0 x 7.0 cm

Cut surface: Greenish tan, and granular with necrosis (30 %)

Gross type

HCC: Expanding nodular

Resection margin

Not involved grossly (safety margin: 1.2 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Representative sections are submitted

Other specimen:

Gallbladder: Unremarkable, grossly

Gross photo: Present

Blocks

T1-5, TB, bile tinged mass and surrounding liver parenchyme x 6

A, labeled as 'No. 3' x 1

L, NB, nontumorous liver parenchyme x 2

RM, resection margin of liver x 1

GB, gallbladder and cystic duct resection margin x 1

MICROSCOPIC:

Hepatocellular carcinoma:

The worst differentiation: IV

The major differentiation: III

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (5 %)

Fibrous capsule formation: Partial capsule

Capsular infiltration: Yes

Septum formation: No

Surgical resection margin invasion: No

[page 2 of 2]
Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: Yes
Intrahepatic metastasis: No
Multicentric occurrence: Yes (main mass and labeled as 'No. 3')

Non-tumor liver pathology

1. Chronic hepatitis:
- 1-1. Etiology: HCV
- 1-2. Grade, lobular: Minimal
- 1-3. Grade, portoperiportal: Mild to moderate
- 1-4. Stage (fibrosis): Septal
2. Dysplastic nodule: No
3. Ductal epithelial dysplasia: No
4. Other liver diseases: No

NOT reported. Gross:

Stomach, antrum, scopic, chronic gastritis

liver,ectomy,hepatocellular carcinoma

T56000, P10, M81703

gallbladder,ectomy,chronic cholecystitis

T57000, P10, M43005

DIAGNOSIS:

Liver, left, lobectomy: Hepatocellular carcinoma

Gallbladder, cholecystectomy: Chronic cholecystitis (autolysis)

Source: NCI Genomic Data Commons file 160a76a0-b452-476e-8481-a18dfbbf39ff (TCGA-DD-AADE.826E81E3-8D51-425F-B514-C0BBCDFA5E1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).